Surgical pathology report (de-identified scan), TCGA case TCGA-F2-7273, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-7273-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

FSA: Liver, biopsy

- Cholestasis, mesothelial lined cyst, no metastatic carcinoma identified

FSB: Common bile duct margin, excision

- No carcinoma identified

FSC: Pancreatic duct margin, excision

- No carcinoma identified

D: Portal lymph nodes, dissection

- No metastatic carcinoma identified (0/9)

E: Hepatic artery lymph nodes, dissection

- No metastatic carcinoma identified (0/12 lymph nodes and lymph node fragments)

F: Gallbladder, cholecystectomy

- Chronic cholecystitis, no stones identified

G: Pancreaticoduodenectomy, Whipple procedure

Tumor Histologic Type: invasive ductal adenocarcinoma

Histologic grade: moderate to poorly differentiated

Tumor size: 4.2 cm

Extent of invasion:

Peripancreatic soft tissues: involved (G9)

Duodenum: involved (G14)

Ampulla: involved (G7)

Lymphatic Invasion: present (G12)

Venous Invasion: not identified

Perineural Invasion: present

Surgical Margins:

Pancreatic neck: not involved

Bile duct: not involved

Posterior pancreatic surface (deep radial margin): positive at site of SMA (G9) and site of portal vein (G11)

Peripancreatic soft tissues: involved posteriorly, see above

[page 2 of 5]
Proximal (gastric): not involved
Distal (duodenal): not involved

Regional lymph nodes:
Total number with metastasis: 3
Total number examined: 32

Additional pathologic findings: none

AJCC Stage: pT3 pN1 pMx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:

A frozen section consultation was requested by _____ at

FSA1: Liver, biopsy

- Liver with bile stasis, mild inflammation and detached peritoneum versus mesothelial cyst. No malignancy identified.

FSB1: Bile duct margin, excision

- No carcinoma identified

FSC1: Pancreatic duct margin, excision

- Chronic pancreatitis with fibrosis; no carcinoma identified

Drs. at

Drs. at

Frozen Section Pathologist: M.D., Ph.D.

Clinical History:

_____ year-old male with a mass in the pancreatic head and obstructive jaundice. The mass was not previously biopsied.

Gross Description:

Received are seven appropriately labeled containers.

Container A is additionally labeled "liver biopsy." The container holds three beige/tan soft tissue fragments measuring in aggregate 1.5 x 1.0 x 0.7 cm frozen and totally submitted as FSA1,

Container B is additionally labeled "common bile duct margin."

[page 3 of 5]
The container holds a 1.5 x 0.2 x 0.2 cm red/beige/tan soft tissue fragment frozen and totally submitted as FSB1, .

Container C is additionally labeled "pancreatic duct margin." The container holds a 0.9 x 0.2 x 0.2 cm red/beige/tan soft tissue fragment frozen and totally submitted as FSC1, .

Container D is additionally labeled "portal lymph nodes." The container holds a 3.5 x 1.5 x 0.2 cm tan fibroadipose soft tissue fragment with several small lymph node candidates palpated within ranging in size from 0.2 to 0.6 cm. The specimen is totally submitted in blocks D1 and D2,

Container E is additionally labeled "hepatic artery lymph nodes." The container holds an aggregate of tan fibroadipose soft tissue fragments loosely measuring 3 x 2 x 0.7 cm. Several firm lymph node fragments are palpated within the specimen. The specimen is totally submitted in blocks E1 and E2,

Container F is additionally labeled "gallbladder." The container holds a cholecystectomy specimen measuring 8 x 3.5 x 2.5 cm. The serosal surface is pink/tan and smooth with a rough liver bed resection surface. The mucosa is hemorrhagic, velvety and finely trabeculated. The wall is uniform 0.2 to 0.4 cm in thickness. There are no stones. There are scant hemorrhagic luminal contents. No mucosal or mural lesions are noted.

Block summary:

F1 - resection margin with cystic duct and artery and representative section from fundus

F2 - representative sections from mid body and neck

Container G is additionally labeled "pancreaticoduodenectomy with short stitch at uncinate, long stitch at SMA." The container holds a standard Whipple specimen with the following measurements: distal stomach 7.5 x 5 cm; portion of greater omentum attached to stomach 11 x 4.5 x 1.5 cm; duodenum 24 cm in length x 2.5 cm in average diameter (after fixation); pancreatic head and neck 6 x 4.5 x 4.5 cm. A long stitch marks the pancreatic margin at the SMA and a short stitch marks the uncinate process margin. Inking: common bile duct=yellow, resection margin at pancreatic neck=blue, uncinate process=black, peripancreatic soft tissue=green.

The serosal surface of the stomach and duodenum is tan and smooth. The pancreatic head is very firm. Opening the duodenum reveals erythematous coarse and thickened mucosa at the ampulla.

[page 4 of 5]
The remainder of the stomach and duodenal mucosa is beige/tan, unremarkable, and appropriately folded. The pancreas is sectioned revealing a 4.2 x 4.0 x 4.0 cm white/tan/yellow solid firm mass occupying most of the pancreatic parenchyma in the specimen. The mass has areas of necrotic cystic change along the dorsal pancreatic surface. The tumor constricts the common bile duct to lumen diameter of 1-2 mm. It comes up into the ampulla and undermines the duodenal mucosa. The tumor infiltrates into the duodenal wall proximal to the ampulla as well, extending up to and possibly into the submucosa. The tumor does not involve the pylorus. There is relatively poor demarcation between the mass and the pancreatic neck. To assess distance to pancreatic neck margin the resection surface of the neck is inked blue and sections are taken perpendicular to this surface (true surgical margin at the neck is superseded by the en face G2 section). The mass extends to the inked uncinate margin at short stitch and the margin at the SMA at long stitch. It also abuts peripancreatic soft tissue. Distance to mucosal margins: stomach margin 16 cm, duodenal margin 13 cm, common bile duct margin 1.5 cm

A number of firm lymph nodes are identified in the peripancreatic soft tissue ranging in size from 0.2 to 0.6 cm, submitted per block summary. Tumor was collected by Tissue Procurement.

Block Summary:

- G1 - common bile duct margin, en face
- G2 - pancreatic neck margin, en face
- G3 - gastric mucosal margin, en face
- G4 - duodenal mucosal margin, en face
- G5 - lymph node candidate at the common bile duct, bisected
- G6 - perpendicular sections to the pancreatic neck (inked blue)
- G7 - ampulla section
- G8 - perpendicular margin at uncinate at the surgeon's short stitch (black ink)
- G9 - perpendicular section at the SMA margin at long stitch (green ink)
- G10-G11 representative sections to green inked pancreatic surface, G10 near common bile duct, G11 near the portal vein groove
- G12 - ulcerated duodenal mucosa at ampulla
- G13 - tumor in relation to the common bile duct, two sections
- G14 - tumor undermining duodenal wall
- G15 - pylorus, representative section
- G16 - representative sections of stomach and duodenum
- G17 - multiple peripancreatic lymph node candidates
- G18 - multiple peripancreatic lymph node candidates at base of common bile duct

[page 5 of 5]
G19 - multiple peripancreatic lymph node candidates
G20-G22 multiple perigastric lymph nodes candidates, each
cassette, greater omentum

Light Microscopy:

Light microscopic examination is performed by The frozen
section diagnoses are confirmed.

Permanent sections show invasive ductal adenocarcinoma with mucinous features within pancreatic head, extending into peripancreatic fat, extending through the duodenal wall to undermine the mucosa, and extending posteriorly to the pancreatic posterior soft tissue margin at the site of the SMA and the portal vein. Definite nodal metastasis is identified in block G18. Two soft tissue nodules in block G17 are interpreted as most consistent with complete effacement by metastatic carcinoma.

Source: NCI Genomic Data Commons file f4cce94f-e417-45dd-9ff6-00e330035a68 (TCGA-F2-7273.9517F018-4ECE-459D-B850-E57C26990865.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).